TCGA case TCGA-3B-A9HO — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f6509c51-3bdc-45cc-81fe-5e775236305a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Alive.

Diagnoses (3; GDC holds 4 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 75.7 years (27,664 days); Year of diagnosis: 2012; Metastasis at diagnosis: No Metastasis; Prior treatment: Yes; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 4.6; Tumor width measurement: 2.5.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 8; Tumor length measurement: 25; Tumor width measurement: 15.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 73.7 years (26,914 days); Days to diagnosis: -750 days (-2.1 years); AJCC staging edition: 7th; AJCC pathologic stage: Stage III.
3. Subsequent primary of the abdomen (histology not recorded by GDC). Age at diagnosis: 77.4 years (28,259 days); Days to diagnosis: 595 days (1.6 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 6.2; Tumor length measurement: 4.1; Tumor width measurement: 5.8.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 5.5; Tumor width measurement: 0.3.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 4.1; Tumor width measurement: 5.8.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.3; Tumor length measurement: 6.2; Tumor width measurement: 5.5.

Follow-up (2 entries)
- Days to follow up: 692 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 959 days (2.6 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3B-A9HO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-3B-A9HO-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3B-A9HO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3B-A9HO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: Yes; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Intraabdominal.
- Primary pathology: Margin status: Positive; Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No; Contiguous organ invaded: No; Well diff liposarc prior diagnosis indicator: No.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic depth: 8.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: Abdominal Wall; New tumor event surgery: Yes; Days from index date to new tumor event surgery: -59; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event residual tumor: R0; Disease multifocal indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: Abdominal Wall; New tumor event surgery: Yes; Days from index date to new tumor event surgery: 672; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event residual tumor: R0; Disease multifocal indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Lung; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form, Surgery: Other malignancy surgery type: Lobectomy; Days from index date to other malignancy surgery: -689.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic; Days from index date to pharmaceutical treatment started: -689.
- Other malignancy form, Drug treatment, Administered drug 1: Pharmaceutical therapy drug name: Carboplatin.
- Other malignancy form, Drug treatment, Administered drug 2: Pharmaceutical therapy drug name: Taxol.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No; Days from index date to radiation therapy started: -689.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: The OMF completed by the TSS indicates a hx of prior Lung adenocarcinoma, patient had a lobectomy and received systemic treatment (Cisplatin and Taxol).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 959 days; disease-specific survival: no event (censored), 959 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 595 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3B-A9HO-01A-11D-A386-01): tumor purity 0.31, ploidy 3.73, whole-genome doublings 1.
